Somatic mutation profile of tumor specimen TCGA-R5-A7O7-01A (aliquot TCGA-R5-A7O7-01A-11D-A33T-08) from TCGA case TCGA-R5-A7O7, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 52.0 years (18,984 days).
Specimen TCGA-R5-A7O7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3d2c8c4-1ea2-4284-a810-8643cce83fcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R5-A7O7-10A (Blood Derived Normal), aliquot TCGA-R5-A7O7-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6901358-5c7d-4b55-9ebc-146854c5aa07

The open-access MAF lists 124 somatic variants for this specimen: 88 protein-altering or splice-affecting, 30 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 30, Nonsense Mutation 6, RNA 3, Splice Site 2, Intron 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760640852, CM045607, COSV58683415, COSV58688841; called by muse, mutect2, varscan2
- TP53 | c.799C>G p.R267G | Missense Mutation (SNP) | VAF 11/22 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM120851, COSV52678166, COSV52736883, COSV52827473; called by muse, mutect2
- ABCC2 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.724); catalogued as rs370287805; called by muse, mutect2, varscan2
- ADAD1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.301); catalogued as COSV99636431; called by muse, mutect2, varscan2
- ADAMTS19 | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.709); catalogued as rs553809104, COSV50749496; called by muse, mutect2, varscan2
- AFF2 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV100651452; called by muse, mutect2, varscan2
- ANK3 | c.7813G>T p.E2605* | Nonsense Mutation (SNP) | VAF 22/101 reads (22%) | catalogued as COSV99782309; called by muse, mutect2, varscan2
- ANKS1A | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 11/90 reads (12%) | catalogued as COSV100832969; called by muse, mutect2, varscan2
- ARHGAP39 | c.2806G>A p.D936N (on ENST00000276826 / NM_001308208.2; = p.D967N on NM_025251.2) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99432475; called by muse, mutect2, varscan2
- ASCC3 | c.3302G>A p.R1101H | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as rs778530675, COSV61228304; called by muse, mutect2, varscan2
- BRWD3 | c.3995T>G p.L1332R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV100956651; called by muse, mutect2, varscan2
- C8A | c.988T>C p.Y330H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100776695; called by muse, mutect2
- CACNA1H | c.1274C>T p.T425M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs370007023; called by muse, mutect2, varscan2
- CALD1 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772216381, COSV62645160; called by muse, mutect2, varscan2
- CAPNS1 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV99874731; called by muse, mutect2, varscan2
- CLUAP1 | c.765G>C p.Q255H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.025); catalogued as rs150154906; called by muse, mutect2, varscan2
- COBL | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs375925507, COSV54342465; called by muse, mutect2
- COL11A1 | c.2996C>T p.P999L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100618329, COSV62187922; called by muse, mutect2, varscan2
- COL15A1 | c.656T>G p.L219R | Missense Mutation (SNP) | VAF 30/235 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV100898082; called by muse, mutect2, varscan2
- COL4A1 | c.1967C>A p.S656Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.461); catalogued as COSV101011643, COSV65427867; called by muse, mutect2, varscan2
- COL4A2 | c.2582G>T p.R861L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.055); catalogued as COSV100847533, COSV64628399; called by muse, mutect2
- COLEC12 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as rs757520445, COSV68369152; called by muse, mutect2, varscan2
- DDR2 | c.1352C>G p.S451C | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV100906952, COSV100907032; called by muse, mutect2
- DNAH3 | c.3562G>A p.E1188K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs933235238, COSV99771298; called by muse, mutect2, varscan2
- DNAH5 | c.5986T>A p.C1996S | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV99455422; called by muse, mutect2
- DOCK10 | c.3974G>A p.R1325Q | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.743); catalogued as rs745850719, COSV51347560; called by muse, mutect2, varscan2
- DSCAM | c.2790T>G p.D930E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV101261749; called by muse, mutect2, varscan2
- DSEL | c.1414A>C p.S472R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100025940, COSV59489055; called by muse, mutect2, varscan2
- DST | c.3703G>T p.E1235* (on ENST00000361203 / NM_001374722.1; = p.E909* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV99753876, COSV99760932; called by muse, mutect2, varscan2
- FAM47C | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as rs145034356, COSV100792224, COSV63724689; called by muse, mutect2, varscan2
- FGF9 | c.86G>A p.S29N | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV101211046; called by muse, mutect2, varscan2
- GART | c.1786G>C p.D596H | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV101111438; called by muse, mutect2, varscan2
- GPR101 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1488318325, COSV99981730; called by muse, mutect2, varscan2
- GPR139 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV58502678, COSV58503578; called by muse, mutect2, varscan2
- GTF3C3 | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV99826373, COSV99827112; called by muse, mutect2, varscan2
- HIVEP2 | c.6918G>A p.M2306I | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV99176560; called by muse, mutect2, varscan2
- KCNH8 | c.3216G>C p.W1072C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100111213; called by muse, mutect2, varscan2
- KDM5C | c.1439C>A p.P480Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as BM1323210, COSV100949576, COSV64762787; called by muse, mutect2, varscan2
- KL | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV101199245; called by muse, mutect2, varscan2
- KLHL4 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs754779267, COSV64143000, COSV64147175; called by muse, mutect2, varscan2
- MARCHF4 | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.055); catalogued as COSV99814905; called by muse, mutect2, varscan2
- MAS1L | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.355); catalogued as COSV101009739; called by muse, mutect2, varscan2
- MATR3 | c.1465G>C p.D489H | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV63079929; called by muse, mutect2
- MRPS15 | c.386T>G p.I129S | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV100910951; called by muse, mutect2, varscan2
- MSC | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs753728260, COSV100335782; called by mutect2, varscan2
- MYC | c.1273G>A p.E425K (on ENST00000377970; = p.E440K on NM_002467.6) | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV99422023; called by muse, mutect2
- NLGN1 | c.740T>C p.F247S | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100850384; called by muse, mutect2
- NOTCH3 | c.5293G>A p.A1765T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.083); catalogued as COSV99659247; called by muse, mutect2, varscan2
- OR10K2 | c.635T>C p.L212S | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.249); catalogued as COSV100149702; called by muse, mutect2, varscan2
- OR10R2 | c.830T>C p.F277S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV100936856; called by muse, mutect2
- OR2L8 | c.332C>A p.A111E | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as COSV100594361; called by muse, mutect2, varscan2
- OR5M1 | c.824C>A p.A275E | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101591627; called by muse, mutect2, varscan2
- OR6X1 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.745); catalogued as COSV100020691; called by muse, mutect2, varscan2
- PCDHB6 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50733864; called by muse, varscan2
- PCM1 | c.4358T>G p.I1453R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.923); catalogued as COSV100279745; called by muse, mutect2, varscan2
- PDE4A | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.764); catalogued as COSV100764264; called by muse, mutect2, varscan2
- PDXDC1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.959); catalogued as COSV100363534; called by muse, mutect2, varscan2
- POU6F2 | c.1574A>C p.H525P | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV101302906; called by muse, mutect2
- PRKCB | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100335676; called by muse, mutect2, varscan2
- PRPF39 | c.127C>A p.Q43K | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.042); catalogued as COSV100866058; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | catalogued as rs146650273; called by pindel, varscan2
- RBMS1 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100817139; called by muse, mutect2, varscan2
- SCN5A | c.4018G>A p.V1340I (on ENST00000333535 / NM_198056.3; = p.V1339I on NM_000335.5) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199473605, CM100703, COSV61128014; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERINC2 | c.616T>C p.F206L (on ENST00000373709 / NM_178865.5; = p.F210L on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.693); catalogued as rs782684426, COSV101037178; called by muse, mutect2, varscan2
- SHOX | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs758706054, COSV61860840; called by muse, mutect2, varscan2
- SLC13A2 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200385517, COSV58993146; called by muse, mutect2, varscan2
- SLC26A7 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99404577; called by muse, mutect2, varscan2
- SLC9A3 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53803377, COSV99376767; called by muse, mutect2
- SLITRK2 | c.2383C>T p.Q795* | Nonsense Mutation (SNP) | VAF 18/104 reads (17%) | catalogued as COSV100158332; called by muse, mutect2, varscan2
- SNAP47 | c.1124-1G>T p.X375_splice | Splice Site (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100248543; called by muse, mutect2, varscan2
- SORBS2 | c.226G>A p.G76R (on ENST00000284776 / NM_021069.5; = p.G122R on NM_003603.6) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778612065, COSV99511461; called by muse, mutect2, varscan2
- SYNE1 | c.22453G>A p.G7485R (on ENST00000367255 / NM_182961.4; = p.G7414R on NM_033071.3) | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99583669; called by muse, mutect2, varscan2
- SYT16 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs775256228, COSV70857301; called by muse, mutect2, varscan2
- TBX20 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101282444; called by muse, mutect2, varscan2
- TCEAL2 | c.629T>A p.F210Y | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.158); catalogued as COSV100216453; called by muse, mutect2, varscan2
- TG | c.5854C>T p.R1952W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); catalogued as rs369705913; called by muse, mutect2, varscan2
- TRIM58 | c.942G>T p.Q314H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV63571102; called by muse, mutect2
- TRPM3 | c.2377G>T p.E793* (on ENST00000357533 / NM_001366142.2; = p.E636* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100679137; called by muse, mutect2
- TTBK2 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99142668; called by muse, mutect2, varscan2
- VLDLR | c.325+1G>A p.X109_splice | Splice Site (SNP) | VAF 40/142 reads (28%) | catalogued as rs778298702, COSV101173252; called by muse, mutect2, varscan2
- ZBTB4 | c.3026A>G p.K1009R | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV100043821; called by muse, mutect2, varscan2
- ZC3H11A | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 11/109 reads (10%) | catalogued as COSV100142938; called by muse, mutect2
- ZKSCAN7 | c.1148A>G p.Y383C | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs767976873, COSV99837805; called by muse, mutect2, varscan2
- ZNF106 | c.3118A>G p.K1040E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99783326; called by muse, mutect2, varscan2
- ZNF322 | c.154T>G p.F52V | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV70652028; called by muse, mutect2
- ZNF700 | c.1175G>T p.C392F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54315362; called by muse, mutect2, varscan2
- ZNF808 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs776653190, COSV63121077; called by muse, mutect2, varscan2
- CYFIP1 | c.1448C>G p.A483G | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ABCA12 | c.5988C>A p.G1996= (on ENST00000272895 / NM_173076.3; = p.G1678= on NM_015657.3) | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV55949497, COSV99792556; called by muse, mutect2, varscan2
- ASAP1 | c.2433A>G p.L811= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as COSV100728043; called by muse, mutect2, varscan2
- C8G | c.429G>A p.A143= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs548151906, COSV99812710; called by muse, mutect2, varscan2
- CDR1 | c.612G>A p.K204= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV100983406; called by muse, mutect2, varscan2
- CYLC1 | c.564T>C p.S188= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100255639; called by muse, mutect2, varscan2
- DPYSL3 | c.894G>A p.A298= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs200777055, COSV58331098; called by muse, mutect2, varscan2
- HOOK3 | c.999A>G p.L333= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100296188; called by muse, mutect2, varscan2
- KCNH8 | c.2631G>A p.L877= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV60465010; called by muse, mutect2
- KCNK9 | c.240C>T p.F80= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV57286651; called by muse, mutect2
- KSR2 | c.990C>A p.A330= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100196963; called by muse, mutect2, varscan2
- LRP3 | c.189C>T p.P63= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99473682; called by muse, mutect2, varscan2
- MAP3K11 | c.627C>T p.R209= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs756251314, COSV100482803; called by muse, mutect2, varscan2
- NEB | c.4314C>T p.D1438= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs1419373548, COSV99428943; called by muse, mutect2, varscan2
- OR2T4 | c.186C>G p.V62= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as COSV100822661, COSV63545126; called by muse, mutect2, varscan2
- PAPPA2 | c.3585T>G p.A1195= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV100867476, COSV100868800; called by muse, mutect2, varscan2
- PCDHGA2 | c.132C>T p.F44= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV53988638; called by muse, mutect2, varscan2
- PDE3A | c.1866C>T p.T622= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs565956666, COSV62975105; called by muse, mutect2, varscan2
- PHKA1 | c.24G>A p.G8= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV100264063; called by muse, mutect2, varscan2
- PRDM1 | c.624T>C p.L208= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV100959036; called by muse, mutect2, varscan2
- SLC45A1 | c.1836C>T p.L612= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as rs201524553, COSV99239803; called by muse, mutect2, varscan2
- SORCS1 | c.2022C>G p.A674= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV53844970, COSV53915987; called by muse, mutect2, varscan2
- SSC4D | c.693C>T p.G231= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99300203; called by muse, mutect2, varscan2
- TBX20 | c.63C>T p.A21= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs139984472; called by muse, mutect2, varscan2
- TMEM200C | c.210G>A p.A70= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV101274875; called by muse, mutect2
- TMEM209 | c.864G>A p.K288= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV100390692; called by muse, mutect2, varscan2
- UQCRFS1 | c.363T>G p.T121= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV100508254; called by muse, mutect2, varscan2
- UST | c.969G>A p.T323= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs759024450, COSV100820237; called by muse, mutect2, varscan2
- XKR5 | c.654G>A p.V218= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV101306755; called by muse, mutect2
- ZFHX4 | c.2334C>T p.V778= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs937285124, COSV50515055, COSV50723610; called by muse, mutect2, varscan2
- ZFPM2 | c.2019C>A p.P673= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV65876379; called by muse, mutect2, varscan2
- CDH2 | c.173-22613T>C | Intron (SNP) | VAF 9/73 reads (12%) | catalogued as COSV99298954; called by muse, mutect2, varscan2
- CHCHD2P9 | n.31C>T | RNA (SNP) | VAF 11/75 reads (15%) | catalogued as rs73655713; called by muse, mutect2, varscan2
- COG5 | c.-64T>G | 5'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99709334; called by muse, mutect2
- COL18A1-AS1 | n.1510C>A | RNA (SNP) | VAF 3/24 reads (13%) | catalogued as COSV101181795; called by muse, mutect2
- FAM153CP | n.431G>T | RNA (SNP) | VAF 32/157 reads (20%) | catalogued as COSV101228682; called by muse, mutect2, varscan2
- MYH7 | c.4169+148_4169+150del | Intron (DEL) | VAF 6/46 reads (13%) | called by pindel, varscan2
